Surgical pathology report (de-identified scan), TCGA case TCGA-VF-A8AB, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Pennsylvania, specimen TCGA-VF-A8AB-01A (Primary Tumor).

[page 1 of 2]
Panel: Surgical Pathology Final Report
Date:

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-in progress/incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk [*] in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Collected	Value	Units	Range	Note
Surgical Pathology Final Report	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]
Collection d/t:						
Obs d/t:						
Ordered by:						

Surgical Pathology Report

ICD-O-3
Seminoma NOS 9061/3
Site (B) Testis NOS C62.9
pt 5/30/14

Final Diagnosis

1. Testicle, right; orchiectomy:
- Classical seminoma, confined to the testes.
- Tumor measures 3.9 cm in greatest dimension, grossly.
- No lymphovascular invasion seen.
- Tunica vaginalis, rete testes and epididymis is uninvolved.
- Adjacent seminiferous tubules with tubular atrophy.
- Spermatic cord, vascular, and soft tissue margins are free of tumor.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Pathologist(s)

Gross Description

Specimen #1 designated "right testicle" is received fresh, labeled with the patient's name and medical record number, and consists of a an orchiectomy specimen weighing 52.0 g and measuring 7.5 x 4.4 x 2.0 cm. The testicle is bisected to reveal a yellow, multilobulated, firm, ill circumscribed mass measuring 3.9 x 3.5 x 2.0 cm over all. The external surface of the specimen is inked entirely in blue. Representative sections are submitted as follows: 1A and 1B, vascular and soft tissue margin; 1C through 1G, tumor; 1H and 1I, proximal testicle not involved by tumor; 1J, spermatic

[page 2 of 2]
cord margin.

SUMMARY OF SECTIONS: 10, multiple, representative

Dictated by:

Clinical Information

-year-old man with history of right testicular mass
Pre-Operative Diagnosis: Not specified
Post-Operative Diagnosis: Not specified
Operation: Right radical orchiectomy

Specimen:

1 Right testicle

*** End of report ***

HIST/FA Discrepancy		✓

Source: NCI Genomic Data Commons file 61ebaab5-41ef-4e10-a466-7d688f3687ed (TCGA-VF-A8AB.633B1959-984F-44FE-8804-A88C4B83D280.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).